Somatic mutation profile of tumor specimen 0DBW4A from CCDI case PBBLKN, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 11.9 years (4,329 days).
Specimen 0DBW4A: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 792870be-2729-47fa-945e-bcaacc6adadf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DBW3W (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1701db4a-eaa1-4b23-9362-c7c043463066

The open-access MAF lists 26 somatic variants for this specimen: 17 protein-altering or splice-affecting, 4 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Intron 5, Silent 4, Splice Region 2, Splice Site 2, Nonsense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACACB | c.578G>A p.R193Q | Missense Mutation (SNP) | VAF 126/506 reads (25%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.014); catalogued as rs767203808, COSV58127526; called by muse, mutect2, varscan2
- ATP10B | c.1075C>T p.P359S | Missense Mutation (SNP) | VAF 277/622 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs770370692; called by muse, mutect2, varscan2
- CNTNAP2 | c.3283C>T p.R1095* | Nonsense Mutation (SNP) | VAF 52/372 reads (14%) | catalogued as rs771533907, COSV100662227; called by muse, mutect2, varscan2
- DNAH1 | c.1444+1G>A p.X482_splice | Splice Site (SNP) | VAF 64/425 reads (15%) | catalogued as rs1226330429; called by muse, mutect2, varscan2
- HAGH | c.724C>T p.R242W | Missense Mutation (SNP) | VAF 192/454 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.59); catalogued as rs563988047, COSV68400668; called by muse, mutect2, varscan2
- KDM6A | c.3657G>A p.W1219* | Nonsense Mutation (SNP) | VAF 286/310 reads (92%) | catalogued as COSV100938337, COSV65042442, COSV65048736; called by muse, mutect2, varscan2
- LGALS9 | c.227C>T p.T76M | Missense Mutation (SNP) | VAF 102/1050 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs531082359, COSV56347982; called by muse, mutect2
- UBR3 | c.2911-7A>T | Splice Region (SNP) | VAF 72/548 reads (13%) | catalogued as rs1424424752; called by muse, varscan2
- AADAC | c.1027G>C p.D343H | Missense Mutation (SNP) | VAF 17/419 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CD3D | c.276G>C p.M92I | Missense Mutation (SNP) | VAF 103/612 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); called by muse, mutect2, varscan2
- CTDNEP1 | c.478-2A>T p.X160_splice | Splice Site (SNP) | VAF 78/278 reads (28%) | called by muse, mutect2, varscan2
- FAU | c.76-5T>C | Splice Region (SNP) | VAF 34/745 reads (5%) | called by muse, mutect2
- OR4C3 | c.662A>G p.Y221C | Missense Mutation (SNP) | VAF 21/476 reads (4%) | SIFT tolerated (0.2); PolyPhen benign (0.001); called by muse, mutect2
- RAD21L1 | c.1558G>A p.A520T | Missense Mutation (SNP) | VAF 27/750 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.113); called by muse, mutect2
- UPK3B | c.442C>T p.P148S (on ENST00000257632; = p.P93S on NM_001347684.2) | Missense Mutation (SNP) | VAF 35/548 reads (6%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.046); called by muse, mutect2
- ZBTB38 | c.3389G>A p.C1130Y | Missense Mutation (SNP) | VAF 82/604 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF41 | c.1055A>G p.Q352R | Missense Mutation (SNP) | VAF 208/236 reads (88%) | SIFT deleterious (0); PolyPhen possibly damaging (0.472); called by muse, varscan2
- ABCA8 | c.1965C>T p.C655= | Silent (SNP) | VAF 97/1006 reads (10%) | catalogued as rs781158837, COSV52194068; called by muse, mutect2
- FAT4 | c.13374G>C p.S4458= | Silent (SNP) | VAF 25/755 reads (3%) | catalogued as COSV58693915, COSV58711094; called by muse, mutect2
- IL18RAP | c.1173G>C p.L391= | Silent (SNP) | VAF 28/761 reads (4%) | catalogued as rs1321453366; called by muse, mutect2
- PCDHGA4 | c.84C>T p.G28= | Silent (SNP) | VAF 96/707 reads (14%) | catalogued as COSV53976756; called by muse, mutect2, varscan2
- CENPN | c.355-10C>T | Intron (SNP) | VAF 48/344 reads (14%) | catalogued as rs374811240; called by muse, varscan2
- DNAH12 | c.6930-15864T>C | Intron (SNP) | VAF 57/460 reads (12%) | called by muse, mutect2, varscan2
- EIF2B4 | c.75+42G>A | Intron (SNP) | VAF 43/80 reads (54%) | called by muse, mutect2, varscan2
- HSPD1 | c.870-76A>G | Intron (SNP) | VAF 9/80 reads (11%) | called by muse, varscan2
- VEGFB | c.375-11T>G | Intron (SNP) | VAF 56/650 reads (9%) | catalogued as COSV58536655, COSV58537550; called by muse, mutect2
